Gene-level copy-number profile of tumor specimen TCGA-DQ-5629-01A from TCGA case TCGA-DQ-5629, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; Tumor grade: G2; Age at diagnosis: 64.5 years (23,550 days).
Specimen TCGA-DQ-5629-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.03f47807-3c02-4ae0-be98-57e1f4da07eb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DQ-5629-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 820 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/724258c9-5ff7-48e5-8282-c8c2ef5d13a5

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,274; copy number 2: 16,417; copy number 3: 17,576; copy number 4: 11,156; copy number 5: 9,562; copy number 6: 1,488; copy number 7: 1,657; copy number 8: 60; copy number 9: 94; copy number 10: 436; copy number 12: 29; copy number 13: 54.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DQ-5629-01A-01D-1869-01): tumor purity 0.59, ploidy 3.41, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,330 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:118,614,333–119,140,654, 8 genes, copy number 12 (within-gene range 4–12): PSMC1P12, AL139148.1, TBX15, AL139420.1, AL139420.2, WARS2, WARS2-IT1, RBMX2P3.
- chr2:61,476,032–62,224,731, 21 genes, copy number 12 (within-gene range 4–12): XPO1, AC016727.3, AC016727.2, RPS29P10, RNU6-1145P, AC108039.1, RPS24P7, AC108039.2, FAM161A, RPL31P30, AC107081.2, CCT4, AC107081.1, AC107081.3, COMMD1, Y_RNA, AC018462.1, RPSAP26, AC018462.2, B3GNT2, MIR5192.
- chr2:164,840,661–165,689,407, 9 genes, copy number 7 (within-gene range 6–7): AC019197.1, RNA5SP110, RNA5SP111, SLC38A11, SCN3A, SCN2A, MAPRE1P3, AC011303.1, CSRNP3.
- chr2:170,178,145–180,007,297, 201 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr2:202,201,384–204,307,364, 57 genes, copy number 8: DAZAP2P1, SUMO1, RPL39P14, NOP58, SNORD70, SNORD70B, SNORD11B, SNORD11, AC064836.3, RN7SL753P, PIMREGP1, AC064836.1, RN7SL40P, AC064836.2, BMPR2, H3P8, RPL13AP12, MTCO1P17, MTCO2P17, MTATP6P17, MTCO3P17, MTND3P17, MTND4LP17, MTND4P30, MTCO1P54, FAM117B, ICA1L, AC098831.1, KRT8P15, WDR12, CARF, KRT8P52, AC010900.1, NBEAL1, RPL7P14, AC023271.1, AC023271.2, RPL23AP36, RPL12P16, CYP20A1, RN7SL670P, MRPL50P2, ABI2, AC080075.1, RAPH1, AC125238.2, AC125238.1, CD28, KRT18P39, NPM1P33, RNU6-474P, CTLA4, ICOS, AC009965.2, AC009965.1, AC009498.1, DSTNP5.
- chr3:148,695,994–153,200,017, 106 genes, copy number 10 (broad region; genes not listed).
- chr3:153,384,934–153,980,186, 1 gene, copy number 10 (within-gene range 5–10): LINC02006.
- chr3:153,881,526–155,309,807, 22 genes, copy number 10: AC068985.1, U8, RPL21P42, ARHGEF26-AS1, ARHGEF26, DHX36, AC134026.1, AC134026.2, GPR149, DDX50P2, AC092994.1, SYPL1P1, DYNLL1P5, RPL9P15, AC073359.2, AC073359.1, MME, MME-AS1, LINC01487, STRIT1, AC104831.1, PABPC1P10.
- chr3:155,375,683–155,487,121, 6 genes, copy number 10: AC108729.3, AC108729.2, AC108729.1, RN7SL715P, PLCH1-AS1, PLCH1-AS2.
- chr3:162,486,541–183,888,449, 301 genes, copy number 10 (broad region; genes not listed).
- chr5:58,198–27,121,150, 425 genes, copy number 7–9 (broad region; genes not listed).
- chr7:54,185,071–56,305,526, 61 genes, copy number 7 (broad region; genes not listed).
- chr7:62,275,361–104,907,232, 888 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr7:131,897,289–132,087,992, 2 genes, copy number 8 (within-gene range 6–8): AC009518.1, AC105443.1.
- chr7:132,264,152–132,271,269, 1 gene, copy number 8: AC018643.1.
- chr17:39,461,486–42,811,587, 221 genes, copy number 7–13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 412. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
